CGCI case BLGSP-71-22-00339 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2843599b-b36f-460b-8563-2e022974103f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 8 years; Vital status: Dead; Days to death: 298 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Specified parts of peritoneum; Classification of tumor: primary; Age at diagnosis: 8.3 years (3,038 days); Year of diagnosis: 2015; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 297 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Mesenteric lymph nodes; Sites of involvement: Bone, NOS / Peritoneum, NOS / Liver / Pancreas, NOS / Small intestine / Pleura.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Femoral; Tumor largest dimension diameter: 28 cm.
   Pathology details: Lymph node involved site: Mesenteric.
   Pathology details: Lymph node involved site: Inguinal.
   Pathology details: Lymph node involved site: Supraclavicular.
   Pathology details: Lymph node involved site: Paraaortic.
   Pathology details: Lymph node involved site: Iliac, NOS.
   Pathology details: Lymph node involved site: Retroperitoneal.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: ANHL1131 (Group B - no rituximab); Days to treatment start: 4 days; Days to treatment end: 138 days; Number of cycles: 4; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 4 days; Days to treatment end: 138 days; Number of cycles: 4; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 50.
- Days to follow up: 70 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 70 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 297 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 2831 [Blood test normal range upper: 618].

Other clinical attributes
- Day 0: Weight: 26 kg; Height: 128 cm; BMI: 15.9.

Biospecimens (3 samples)
- Sample BLGSP-71-22-00339-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Omentum; Preservation method: FFPE; Days to sample procurement: 0 days; Tissue collection type: Prospective.
- Sample BLGSP-71-22-00339-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-22-00339-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen; Days to sample procurement: 3 days; Method of sample procurement: Blood Draw; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Partial Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: Iliac; Lymph node involvement site: para-aortic.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Bone; Extranodal involvement site: Ascites/Peritoneum; Extranodal involvement site: Liver; Extranodal involvement site: Pancreas; Extranodal involvement site: Small Intestine; Extranodal involvement site: Pleura/Pleural Effusion.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 2831; Immunophenotypic analysis method: Immunohistochemistry; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- New tumor event: New tumor event type: Locoregional Recurrence.
- Follow-up form: Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease; New tumor event diagnosis indicator: Yes.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 4.
